Somatic mutation profile of tumor specimen TCGA-FB-AAQ0-01A (aliquot TCGA-FB-AAQ0-01A-31D-A40W-08) from TCGA case TCGA-FB-AAQ0, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,988 days).
Specimen TCGA-FB-AAQ0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf6c514-dbbb-40c0-8dca-d71218cc63b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAQ0-11A (Solid Tissue Normal), aliquot TCGA-FB-AAQ0-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad287b7-5961-4a87-b6c0-f2b7a2690c1b

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, 3'UTR 2, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 58/218 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 79/172 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1090G>A p.A364T (on ENST00000272895 / NM_173076.3; = p.A46T on NM_015657.3) | Missense Mutation (SNP) | VAF 142/702 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1353368441, COSV99792659; called by muse, mutect2, varscan2
- ACLY | c.2516C>T p.S839L | Missense Mutation (SNP) | VAF 84/225 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs782729574, COSV100709952; called by muse, mutect2, varscan2
- ARHGAP44 | c.1919G>A p.S640N | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99311744; called by muse, mutect2, varscan2
- CGRRF1 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV99370661; called by muse, mutect2, varscan2
- CLCA1 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs373476030; called by muse, mutect2, varscan2
- DHX36 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100274052; called by muse, mutect2
- DICER1 | c.2876A>T p.K959I | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.671); catalogued as COSV100602677, COSV58620076; called by muse, mutect2
- DMD | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs139772014, COSV63739634; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- EMP3 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 191/595 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV99507629; called by muse, mutect2, varscan2
- GBA3 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 77/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72437868; called by muse, mutect2, varscan2
- HAUS5 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV52548497, COSV99178878; called by muse, mutect2
- IL4R | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 117/474 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV99405496; called by muse, mutect2, varscan2
- MCF2L | c.260G>A p.R87Q (on ENST00000375608; = p.R55Q on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/496 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs752463628, COSV65047603; called by muse, mutect2
- MEF2D | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.342); catalogued as COSV100560505; called by muse, mutect2
- MYH11 | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 68/393 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs756408490, COSV100260579; called by muse, mutect2, varscan2
- PATJ | c.3805A>C p.I1269L | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100220053; called by muse, mutect2
- PCDHB13 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 32/1198 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV53397813; called by muse, mutect2
- PLD5 | c.1126G>A p.V376I (on ENST00000442594; = p.V314I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/643 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs747440422, COSV59138782; called by muse, mutect2, varscan2
- PPP2R1B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376765814; called by muse, mutect2, varscan2
- SDR39U1 | c.388_391del p.D130Ffs*6 | Frame Shift Del (DEL) | VAF 63/291 reads (22%) | catalogued as rs764700184; called by mutect2, pindel, varscan2
- TAP1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100841359; called by muse, mutect2
- TRIM42 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 96/340 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV53886280; called by muse, mutect2, varscan2
- TSHZ3 | c.1409T>G p.V470G | Missense Mutation (SNP) | VAF 151/986 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as COSV99553204; called by muse, mutect2, varscan2
- TTN | c.69139C>T p.R23047C (on ENST00000591111; = p.R15623C on NM_003319.4) | Missense Mutation (SNP) | VAF 45/186 reads (24%) | PolyPhen probably damaging (0.999); catalogued as rs771595253, COSV59998073; called by muse, mutect2, varscan2
- USP10 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 169/618 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.619); catalogued as rs774568908, COSV54747160; called by muse, mutect2, varscan2
- UTRN | c.1360A>C p.K454Q | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100840778; called by muse, mutect2, varscan2
- WNT3A | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as rs1488574529, COSV99469606, COSV99470314; called by muse, mutect2
- XKR4 | c.687C>A p.S229R | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.135); catalogued as COSV59305969; called by muse, mutect2, varscan2
- PUS3 | c.1307_1310dup p.E437Dfs*2 | Nonsense Mutation (INS) | VAF 268/872 reads (31%) | called by mutect2, pindel, varscan2
- ALG1L | c.291G>A p.V97= | Silent (SNP) | VAF 17/259 reads (7%) | catalogued as COSV61075935; called by muse, mutect2
- CAND2 | c.3366C>T p.Y1122= (on ENST00000456430 / NM_001162499.2; = p.Y1005= on NM_012298.3) | Silent (SNP) | VAF 81/340 reads (24%) | catalogued as rs367749511; called by muse, mutect2, varscan2
- CYP7A1 | c.1308C>G p.P436= | Silent (SNP) | VAF 235/722 reads (33%) | catalogued as COSV100052684; called by muse, mutect2, varscan2
- DNAH10 | c.4944C>T p.C1648= (on ENST00000409039; = p.C1587= on NM_207437.3) | Silent (SNP) | VAF 22/505 reads (4%) | catalogued as rs746224204, COSV68997383; called by muse, mutect2
- MKRN3 | c.603G>A p.A201= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as rs1000780930, COSV58808679; called by muse, mutect2, varscan2
- NLRP9 | c.1017G>A p.T339= | Silent (SNP) | VAF 106/606 reads (17%) | catalogued as COSV100243672; called by muse, mutect2, varscan2
- NOL4 | c.1170C>T p.D390= | Silent (SNP) | VAF 26/558 reads (5%) | catalogued as rs1253792175, COSV99308963; called by muse, mutect2
- OR9A4 | c.144C>T p.V48= | Silent (SNP) | VAF 22/748 reads (3%) | catalogued as COSV101516583; called by muse, mutect2
- SLC35B2 | c.438T>A p.G146= | Silent (SNP) | VAF 107/323 reads (33%) | catalogued as COSV99241557; called by muse, mutect2, varscan2
- TNFRSF1B | c.399G>T p.G133= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV100884212; called by muse, mutect2, varscan2
- FUT7 | chr9:137034743 T>A | 5'Flank (SNP) | VAF 180/364 reads (49%) | called by muse, mutect2, varscan2
- LHX6 | c.*17G>A | 3'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs374714258, COSV100493653; called by muse, varscan2
- ZDHHC4 | c.*1C>G | 3'UTR (SNP) | VAF 148/549 reads (27%) | catalogued as COSV100254128; called by muse, mutect2, varscan2
